Gene-level copy-number profile of tumor specimen TCGA-TN-A7HL-01A from TCGA case TCGA-TN-A7HL, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hypopharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.5 years (21,731 days).
Specimen TCGA-TN-A7HL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.8d24c7c4-d9bc-43a1-ad30-849e49b12925.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TN-A7HL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/98aa0dff-0402-454b-b2fd-0d0d1daa45d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,455; copy number 2: 46,439; copy number 3: 5,436; copy number 4: 360; copy number 8: 1; copy number 9: 4; copy number 10: 106; copy number 11: 13; copy number 15: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-TN-A7HL-01A-11D-A34I-01): tumor purity 0.47, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 129 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:1,041,655–7,478,320, 111 genes, copy number 10–15 (broad region; genes not listed).
- chr14:49,373,966–49,599,164, 5 genes, copy number 8–9 (within-gene range 1–9): ATP5MC2P2, RNA5SP384, RPS29, RPL32P29, RN7SL1.
- chr20:32,005,671–32,031,591, 1 gene, copy number 11 (within-gene range 4–11): AL031658.1.
- chr20:32,010,438–32,335,011, 12 genes, copy number 11 (within-gene range 4–11): CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B.

Autosomal genes at a single copy (total copy number 1): 5,075. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
